CCDI case PBBUGV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/d49108de-164e-48c3-aa8c-2ee9f0edeca2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Cervix uteri; Age at diagnosis: 13.7 years (5,009 days).

Biospecimens (3 samples)
- Sample 0DI6KN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI6KW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJ4BT: Tissue type: Tumor; Specimen type: Solid Tissue.
